CPTAC case 11LU013 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a231aaba-b584-42c4-96a9-f010bd1b3c66

Demographics
Sex at birth: male; Race: asian; Year of birth: 1956; Country of birth: Vietnam.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 59.2 years (21,627 days); Year of diagnosis: 2015; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Residual disease: R0; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 6 cm (a second GDC size field records 5.5 cm); Lymph node involvement: Positive; Lymph nodes positive: 4; Lymph nodes tested: 7; Margin status: Uninvolved.

Other clinical attributes
- Weight: 52 kg; Height: 156 cm; BMI: 21.37.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample 9f905736-f662-41d6-b3ac-16758d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 6 days; Initial weight: 235 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide 9f905736-f662-41d6-b3ac-16758d_D1_D1: Section location: not specified; Percent tumor nuclei: 70; Percent necrosis: 10.
- Sample c7788b82-8190-4784-ab76-0d1185: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Method of sample procurement: Blood Draw.
